Somatic mutation profile of tumor specimen TARGET-10-PATMYZ-09A (aliquot TARGET-10-PATMYZ-09A-01D) from TARGET case TARGET-10-PATMYZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.1 years (4,421 days).
Specimen TARGET-10-PATMYZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 698dd996-2a06-4072-96f5-46f1d4f185ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATMYZ-10A (Blood Derived Normal), aliquot TARGET-10-PATMYZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ac38b79-d357-4c83-8d6f-ff138783934d

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Nonsense Mutation 3, 5'UTR 3, Intron 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP32 | c.5356G>A p.G1786R (on ENST00000310343 / NM_001378025.1; = p.G1437R on NM_014715.4) | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100087254, COSV59856390; called by muse, mutect2, varscan2
- ARHGEF4 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs749396177, COSV58130970; called by muse, mutect2, varscan2
- BCL11B | c.2505G>C p.Q835H (on ENST00000357195 / NM_001282237.2; = p.Q764H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61736979; called by muse, mutect2, varscan2
- BCOR | c.4378A>G p.K1460E (on ENST00000378444 / NM_001123385.2; = p.K1426E on NM_017745.6) | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV60719781; called by muse, mutect2, varscan2
- CUL1 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57392955; called by muse, mutect2, varscan2
- MROH5 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs373322968; called by muse, mutect2, varscan2
- NOTCH1 | c.4847T>A p.I1616N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53028112; called by muse, mutect2
- PDE8B | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV53746599; called by muse, mutect2, varscan2
- PKHD1 | c.8286C>G p.D2762E | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61859285, COSV61861052; called by muse, mutect2, varscan2
- PRICKLE1 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 56/127 reads (44%) | catalogued as COSV61547253; called by muse, mutect2, varscan2
- PTPRC | c.2593G>A p.G865R | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61406654; called by muse, mutect2
- RNPEPL1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs778464068, COSV54372120; called by muse, mutect2, varscan2
- RUNX1 | c.398A>G p.D133G (on ENST00000344691 / NM_001001890.3; = p.D160G on NM_001754.5) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55873524, COSV55880140; called by muse, mutect2, varscan2
- SFTPD | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs148025651; called by muse, mutect2, varscan2
- SLC12A1 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201820156; called by muse, mutect2, varscan2
- SUPT5H | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100781981, COSV63242475; called by muse, mutect2, varscan2
- SUZ12 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV59503796; called by muse, mutect2, varscan2
- TCHH | c.5233C>T p.R1745C | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs760326208, COSV64274740; called by muse, mutect2, varscan2
- WDR17 | c.3325G>T p.E1109* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV54585206; called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | called by pindel, varscan2
- MED12 | c.276del p.K93Sfs*4 | Frame Shift Del (DEL) | VAF 7/10 reads (70%) | called by pindel*, varscan2
- ARHGAP30 | c.2958A>G p.R986= (on ENST00000368013 / NM_001025598.2; = p.R775= on NM_181720.3) | Silent (SNP) | VAF 71/146 reads (49%) | called by muse, mutect2, varscan2
- D2HGDH | c.1242C>T p.I414= | Silent (SNP) | VAF 36/63 reads (57%) | catalogued as rs758849873; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHL4 | c.369C>T p.R123= | Silent (SNP) | VAF 20/21 reads (95%) | catalogued as COSV64138958; called by muse, mutect2, varscan2
- SULF2 | c.1503C>T p.S501= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs770595940, COSV63415099; called by muse, mutect2, varscan2
- TAGAP | c.951G>A p.V317= | Silent (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- FRG1 | c.-75_-63del | 5'UTR (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- PPP2R5C | c.1151+9G>A | Intron (SNP) | VAF 14/66 reads (21%) | catalogued as COSV58276967; called by muse, mutect2, varscan2
- RPS18 | c.-22C>T | 5'UTR (SNP) | VAF 55/102 reads (54%) | catalogued as rs764608866; called by muse, mutect2, varscan2
- SLC22A7 | c.399+38G>A | Intron (SNP) | VAF 32/72 reads (44%) | catalogued as rs777640999; called by muse, mutect2, varscan2
- VGLL2 | c.-124C>T | 5'UTR (SNP) | VAF 5/10 reads (50%) | catalogued as rs1182943974, COSV100409834; called by muse, mutect2, varscan2
- ZSCAN18 | c.-119-46G>A | Intron (SNP) | VAF 16/27 reads (59%) | catalogued as rs766769226; called by muse, mutect2, varscan2
